Somatic mutation profile of tumor specimen TCGA-FY-A3ON-01A (aliquot TCGA-FY-A3ON-01A-11D-A21Z-08) from TCGA case TCGA-FY-A3ON, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 20.3 years (7,403 days).
Specimen TCGA-FY-A3ON-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6b242fa-fbc8-44e0-b134-abe2fe62b555.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3ON-10A (Blood Derived Normal), aliquot TCGA-FY-A3ON-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3301651b-f049-4078-bfe6-d9677d631a57

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DNMT3A | c.2296_2297del p.K766Efs*15 | Frame Shift Del (DEL) | VAF 31/233 reads (13%) | catalogued as rs750475955, COSV53041991; called by mutect2, pindel, varscan2
- MAP1B | c.846G>C p.M282I | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as COSV57105900; called by muse, mutect2
- SUFU | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | catalogued as COSV100883047, COSV64016252; called by muse, mutect2, varscan2
